Somatic mutation profile of tumor specimen TCGA-13-1512-01A (aliquot TCGA-13-1512-01A-01W-0545-08) from TCGA case TCGA-13-1512, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.6 years (18,134 days).
Specimen TCGA-13-1512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b525c93-d1b2-4d19-bce5-bdb15670d505.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1512-10A (Blood Derived Normal), aliquot TCGA-13-1512-10A-01W-0546-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6abbbfe0-61f3-47b7-812f-4b6976dd0889

The open-access MAF lists 70 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 17, Frame Shift Ins 4, Splice Site 2, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 125/148 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AXL | c.70T>G p.C24G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.197); catalogued as COSV56564174; called by muse, mutect2, varscan2
- CARNMT1 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 137/316 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65190125; called by muse, mutect2, varscan2
- CCDC38 | c.882C>G p.S294R | Missense Mutation (SNP) | VAF 162/214 reads (76%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100717840; called by muse, mutect2, varscan2
- CCDC69 | c.60A>T p.E20D | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV62599097; called by muse, mutect2, varscan2
- CHAD | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs35218093; called by muse, mutect2, varscan2
- COL5A1 | c.4969G>A p.D1657N | Missense Mutation (SNP) | VAF 418/482 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs892181156, COSV65665511; called by muse, mutect2, varscan2
- CTTN | c.932G>C p.G311A | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV57230385, COSV57231742, COSV57234480; called by muse, mutect2, varscan2
- DENND3 | c.1499G>C p.R500T | Missense Mutation (SNP) | VAF 116/164 reads (71%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99371609; called by muse, mutect2, varscan2
- DIDO1 | c.5435C>T p.S1812L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56614658; called by muse, mutect2
- DIDO1 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV56614671; called by muse, mutect2, varscan2
- ERVFRD-1 | c.79A>G p.K27E | Missense Mutation (SNP) | VAF 118/134 reads (88%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as COSV65368655; called by muse, mutect2, varscan2
- F11R | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 104/182 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57036159; called by muse, mutect2, varscan2
- FAM117A | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 159/338 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.308); catalogued as COSV53630803; called by muse, mutect2, varscan2
- GTF3C1 | c.433T>G p.W145G | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62239145; called by muse, mutect2
- HOXC8 | c.721A>C p.K241Q | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV50000458; called by muse, mutect2, varscan2
- IQGAP3 | c.3388C>G p.L1130V | Missense Mutation (SNP) | VAF 651/1024 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV63249587; called by muse, mutect2, varscan2
- IRAK1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64110093; called by muse, mutect2, varscan2
- LHX4 | c.777A>T p.R259= | Splice Region (SNP) | VAF 46/109 reads (42%) | catalogued as COSV55373189; called by muse, mutect2, varscan2
- LMLN | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 144/178 reads (81%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV99502665; called by muse, mutect2, varscan2
- MAP1S | c.2550dup p.K851Qfs*54 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | catalogued as rs756980586; called by mutect2, varscan2
- MUC16 | c.42202A>G p.T14068A | Missense Mutation (SNP) | VAF 120/155 reads (77%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.878); catalogued as COSV66690067; called by muse, mutect2, varscan2
- NASP | c.1928A>G p.K643R | Missense Mutation (SNP) | VAF 165/391 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV59645916; called by muse, mutect2, varscan2
- NEB | c.1064A>G p.N355S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.992); catalogued as COSV99427443; called by muse, mutect2, varscan2
- NT5C3A | c.560T>A p.L187H (on ENST00000610140 / NM_001374335.1; = p.L153H on NM_016489.13) | Missense Mutation (SNP) | VAF 165/498 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54236978; called by muse, mutect2, varscan2
- PCSK2 | c.1086C>G p.N362K | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV52727067; called by muse, mutect2, varscan2
- PDCD11 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 307/435 reads (71%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV63933126; called by muse, mutect2, varscan2
- PDE4DIP | c.6689T>G p.I2230S | Missense Mutation (SNP) | VAF 138/603 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV100521550; called by muse, mutect2, varscan2
- PKN1 | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV54395018; called by muse, mutect2, varscan2
- RDH5 | c.718dup p.A240Gfs*19 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | catalogued as rs753378940; called by pindel, varscan2
- SBF1 | c.2744dup p.S916Qfs*11 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | catalogued as rs781322321; called by pindel, varscan2
- SCARA3 | c.1568G>C p.G523A | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs779257703, COSV57269414; called by muse, mutect2
- SCN3A | c.4861C>T p.R1621* | Nonsense Mutation (SNP) | VAF 444/1236 reads (36%) | catalogued as rs1553517389, COSV51802367, COSV51805129; called by muse, mutect2, varscan2
- SEPTIN8 | c.1114C>A p.H372N | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV51523386; called by muse, mutect2, varscan2
- SIRPA | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 167/379 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs2422666, COSV61536867; called by muse, mutect2, varscan2
- STAT5B | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 206/288 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV53180728; called by muse, mutect2, varscan2
- SZT2 | c.9548A>T p.E3183V (on ENST00000634258 / NM_001365999.1; = p.E3126V on NM_015284.4) | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65094185, COSV65095060; called by muse, mutect2, varscan2
- TACC3 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs776393463, COSV57603037; called by muse, mutect2, varscan2
- TM4SF18 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs777428789, COSV56058582; called by muse, mutect2, varscan2
- TMC2 | c.1435C>T p.L479F | Missense Mutation (SNP) | VAF 376/935 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100727952; called by muse, mutect2, varscan2
- TNN | c.807G>C p.Q269H | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.903); catalogued as COSV53422110; called by muse, mutect2, varscan2
- TRIM26 | c.673A>C p.K225Q | Missense Mutation (SNP) | VAF 150/180 reads (83%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV68962914; called by muse, mutect2, varscan2
- TRIM67 | c.2318C>A p.T773N | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as COSV64158203; called by muse, mutect2, varscan2
- VPS50 | c.1178T>G p.L393R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.222); catalogued as COSV58505914; called by muse, mutect2, varscan2
- ZBTB18 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 69/118 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs748735173, COSV62396351; called by muse, mutect2, varscan2
- ZFYVE27 | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 86/127 reads (68%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61746338, COSV61747197; called by muse, mutect2, varscan2
- ZNF521 | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 199/521 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs780811669, COSV64122934, COSV64125761; called by muse, mutect2, varscan2
- ELMO3 | c.695_700del p.N232_L233del (on ENST00000652269; = p.N179_L180del on NM_024712.5) | In Frame Del (DEL) | VAF 76/97 reads (78%) | called by mutect2, pindel, varscan2
- GCHFR | c.132-13_144del p.X44_splice | Splice Site (DEL) | VAF 20/102 reads (20%) | called by mutect2, pindel
- ITSN2 | c.947_971del p.Q316Lfs*62 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel
- SLC4A3 | c.2184dup p.L729Afs*47 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- YTHDC2 | c.1493_1495+3del p.X498_splice | Splice Site (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel
- BAG4 | c.1233T>A p.L411= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV54859298; called by muse, mutect2, varscan2
- CEP120 | c.1314A>G p.E438= | Silent (SNP) | VAF 130/426 reads (31%) | catalogued as COSV60264228; called by muse, mutect2, varscan2
- NAPRT | c.1404C>G p.A468= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV52783022; called by muse, mutect2
- NF1 | c.2139C>T p.L713= | Silent (SNP) | VAF 19/424 reads (4%) | catalogued as COSV100648168; called by muse, mutect2
- NUP210 | c.3663C>T p.D1221= | Silent (SNP) | VAF 41/53 reads (77%) | catalogued as COSV54402894; called by muse, mutect2, varscan2
- PEX1 | c.669G>A p.V223= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV50394885; called by muse, mutect2, varscan2
- PIK3CA | c.2400C>A p.I800= | Silent (SNP) | VAF 75/214 reads (35%) | catalogued as COSV55885804; called by muse, mutect2, varscan2
- PLEC | c.13602G>A p.L4534= (on ENST00000322810 / NM_201380.4; = p.L4424= on NM_000445.5) | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100518514; called by muse, mutect2
- RPS6KA2 | c.1482C>T p.L494= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV55830386; called by muse, mutect2
- RUNX2 | c.969C>A p.S323= | Silent (SNP) | VAF 203/281 reads (72%) | catalogued as COSV61839054; called by muse, mutect2, varscan2
- SFRP2 | c.816G>C p.S272= | Silent (SNP) | VAF 94/143 reads (66%) | catalogued as COSV56836871, COSV56837384; called by muse, mutect2, varscan2
- SLC38A7 | c.54T>C p.D18= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV54702364; called by muse, mutect2, varscan2
- SPTBN4 | c.6315C>T p.S2105= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58944147; called by muse, mutect2
- SYNE2 | c.18048G>A p.K6016= | Silent (SNP) | VAF 250/362 reads (69%) | catalogued as COSV100648420; called by mutect2, varscan2
- THSD7A | c.570T>G p.P190= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV70260758; called by muse, mutect2, varscan2
- TTC13 | c.1647G>A p.S549= | Silent (SNP) | VAF 146/403 reads (36%) | catalogued as rs1157441384, COSV64167834; called by muse, mutect2, varscan2
- ZZZ3 | c.1473A>G p.E491= | Silent (SNP) | VAF 147/271 reads (54%) | catalogued as rs984714217, COSV66231355; called by muse, mutect2, varscan2
- ARHGEF1 | c.-20+1185T>A | Intron (SNP) | VAF 30/96 reads (31%) | catalogued as COSV55738079; called by muse, mutect2, varscan2
